Surgical pathology report (de-identified scan), TCGA case TCGA-FG-A60K, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-A60K-01A (Primary Tumor).

[page 1 of 2]
Result Detail

Pathology Result: Surgical Pathology Department

Specimen Collected Date: Specimen Received Date:
Order Number: Ordering Provider:
Medical Record Number: Facility:
Status: F

Accession #:
Pathologist:
Date of Procedure:
Date Received:
Submitting Physician:
Location:

Addendum Present

FINAL DIAGNOSIS
A. MEDIAL FRONTAL TUMOR, C. DEEP, AND D. RIGHT FRONTAL TUMOR, BIOPSIES AND EXCISION.

--OLIGOASTROCYTOMA (WHO GRADE II), SEE NOTE.

Note: The has predominately oligodendroglial features, comprising approximately 75% of the tumor represented. Mitotic figures are not identified and there is mild cellular atypia. Immunohistochemistry with antibody directed against mutant IDH1 R132H and analysis for 1p and 19q deletions will be performed and the results reported in an addendum.

B. MARGIN, BIOPSY:
--FRAGMENT OF MINIMALLY HYPERCELLULAR CEREBRAL CORTEX, NO SOLID TUMOR IDENTIFIED.

Out By Electronically Signed

Intraoperative Consultation:
Microscopic diagnosis:

FSa1: Medial frontal tumor biopsy: consistent with infiltrating glioma.
FSB1: Margin: Minimal hypercellularity.
FSC1: Deep: Infiltrating glioma without obvious anaplasia.

Addendum/Procedures:
Addendum Date Ordered: Status: Signed Out
Date Complete:
Date Reported:

Addendum Diagnosis
Immunohistochemistry with antibody directed against mutant IDH1 R132H is reactive (positive) in the tumor (block D2).

Electronically Signed Out By
Addendum Date Ordered: Status: Signed Out
Date Complete:
Date Reported:

Addendum Diagnosis
Interphase fluorescence in situ hybridization performed at the shows losses of both chromosomes 1p and 19q. A copy of the report from the is on file in the

Electronically Signed Out By

Clinical History:
Right brain tumor

Specimens Submitted As:
A:MEDIAL FRONTAL TUMOR
B:MARGIN
C:DEEP

ICD-O-3
Oligoastrocytoma NOS
9382/3
Site: Supratentorial NOS
path Brain, frontal lobe
C71.0
C71.1
4/16/13

[page 2 of 2]
D:RIGHT FRONTAL TUMOR

Gross Description:

A: Received fresh for intraoperative consultation labeled with patient's name and hospital number, and "medial frontal tumor" are fragments of tan-white soft tissue measuring 0.5 x 0.5 x 0.2 cm in aggregate. Portion of the specimen is submitted for frozen evaluation and the remainder of the specimen is entirely submitted in 2 cassettes.

B: Received fresh for intraoperative consultation labeled with patient's name and hospital number, and "margin" are fragments of tan-white soft tissue measuring 0.3 x 0.2 x 0.2 cm in aggregate. The specimen is entirely submitted for frozen evaluation and the remainder of the specimen is entirely submitted in 1 cassettes.

C: Received fresh for intraoperative consultation labeled with patient's name and hospital number, and "deep" are fragments of tan-white soft tissue measuring 0.5 x 0.2 x 0.2 cm in aggregate. Portion of the specimen is submitted for frozen evaluation and the remainder of the specimen is entirely submitted in 2 cassettes.

D: Received in formalin, labeled with the patient's name and number, are multiple segments of irregular, opaque white to pink-tan soft tissue measuring in aggregate 3.6 x 2.5 x 0.6 cm. Submitted in toto in 2 cassettes.

Source: NCI Genomic Data Commons file 7b011ef8-cac9-4432-b79b-e56260e596fd (TCGA-FG-A60K.EA14BE97-37B4-4D79-B3C0-D0C121BC8E62.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).